MMRF case MMRF_2026 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/93fe2dcd-74b6-4fc8-a0f0-5c21ca70302f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.1 years (22,322 days); ISS stage: I; Days to last known disease status: 917 days (2.5 years); Days to last follow up: 917 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 917 days (2.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 918 days (2.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 917.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -34 (ECOG 0): M Protein 3.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 99.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 44.1 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 1.53 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Glucose 6.93 mmol/L; C-Reactive Protein 0.04 mg/dL.
- Day 58 (ECOG 0): M Protein 2.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 67.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 30.1 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.72 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 7.9 g/dL; Glucose 5.78 mmol/L.
- Day 149 (ECOG 0): M Protein 2.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 82.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 35.5 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 8.5 g/dL; Glucose 11.5 mmol/L.
- Day 240 (ECOG 0): M Protein 2.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 49.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 25.4 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.67 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 7.8 g/dL; Glucose 7.43 mmol/L.
- Day 324 (ECOG 0): M Protein 2.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.4 mg/dL; Immunoglobulin G 24 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 7.8 g/dL; Glucose 12.5 mmol/L.
- Day 415 (ECOG 0): M Protein 1.83 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 44.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 21.7 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 10.2 mmol/L.
- Day 548 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 26.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.9 mg/dL; Immunoglobulin G 23.3 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 8.3 g/dL; Glucose 2.86 mmol/L.
- Day 604 (ECOG 0): M Protein 1.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 6.1 g/dL; Glucose 16.6 mmol/L.
- Day 730 (ECOG 0): M Protein 1.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.1 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 17.6 mmol/L.
- Day 823 (ECOG 0): M Protein 1.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 67.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 25.1 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.12 ×10⁹/L; Absolute Neutrophil 1.38 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.7 g/dL; Glucose 5.56 mmol/L.
- Day 912 (ECOG 0): M Protein 1.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.7 mg/dL; Immunoglobulin G 21.7 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.93 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day -34: Weight: 119 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2026_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -34 days.
- Sample MMRF_2026_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -34 days.
